Somatic mutation profile of tumor specimen TCGA-DX-A6YS-01A (aliquot TCGA-DX-A6YS-01A-12D-A351-09) from TCGA case TCGA-DX-A6YS, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 61.1 years (22,310 days).
Specimen TCGA-DX-A6YS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d40f0d9e-6002-49f7-a90c-484b554ee709.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YS-10A (Blood Derived Normal), aliquot TCGA-DX-A6YS-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a56a7c-90eb-40ce-b208-c2b7b4894691

The open-access MAF lists 141 somatic variants for this specimen: 119 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 20, Splice Site 5, Nonsense Mutation 3, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.2579C>A p.A860E | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99220789; called by muse, mutect2
- ANKRD35 | c.41T>G p.V14G | Missense Mutation (SNP) | VAF 78/92 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100841627; called by muse, varscan2
- APOB | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV51926627, COSV99263540; called by muse, mutect2
- ART5 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100731564; called by mutect2, varscan2
- ATAD5 | c.3934G>C p.D1312H | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100429649, COSV100430302; called by muse, mutect2, varscan2
- ATP2A3 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.082); catalogued as rs771308476, COSV99988768; called by muse, mutect2, varscan2
- BAG4 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as COSV99781708; called by muse, mutect2, varscan2
- C1orf158 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV55346721, COSV99847197; called by muse, mutect2, varscan2
- C7 | c.2285G>T p.S762I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV100495400, COSV100496074; called by muse, mutect2
- C8orf33 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100510460; called by muse, mutect2, varscan2
- CACNA1H | c.2419A>T p.T807S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100670765; called by muse, mutect2, varscan2
- CACNB4 | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99137754; called by muse, mutect2, varscan2
- CADPS | c.3832G>A p.D1278N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as rs992421878, COSV99335875; called by muse, mutect2, varscan2
- CATSPER1 | c.169T>A p.S57T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as COSV100375612; called by muse, mutect2, varscan2
- CCDC158 | c.3129A>T p.K1043N | Missense Mutation (SNP) | VAF 478/710 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV101187150; called by muse, mutect2, varscan2
- CLK2 | c.1312C>A p.L438M (on ENST00000368361 / NM_001294339.2; = p.L437M on NM_003993.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100226584; called by muse, mutect2
- CPT1A | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV99680572; called by muse, mutect2, varscan2
- CRLF3 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); catalogued as COSV100158266; called by muse, mutect2
- CUL9 | c.2335G>T p.V779F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as COSV99334748; called by muse, mutect2, varscan2
- DCP1B | c.1097C>A p.A366E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99767182; called by muse, mutect2
- DCT | c.120C>A p.C40* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100986101; called by mutect2, varscan2
- DNAH11 | c.4471C>A p.Q1491K | Missense Mutation (SNP) | VAF 40/379 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV100177045; called by muse, mutect2, varscan2
- DNASE1 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV99892301; called by muse, mutect2, varscan2
- DPY30 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99704955; called by muse, mutect2
- DRAXIN | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs555637148, COSV99610552; called by muse, mutect2, varscan2
- ECI2 | c.553A>G p.I185V (on ENST00000380118 / NM_206836.3; = p.I155V on NM_006117.2) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746632168, COSV60988174; called by muse, mutect2, varscan2
- ELOA2 | c.382C>A p.H128N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1245197198, COSV99795895; called by muse, mutect2, varscan2
- EPC1 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99552548; called by muse, mutect2, varscan2
- ETFA | c.841T>G p.S281A | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99144172; called by muse, mutect2
- FAM214A | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as rs1444434826, COSV99957594; called by muse, mutect2
- FAM71B | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as rs370119273; called by muse, varscan2
- FCGBP | c.8911G>A p.G2971R | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759513585; called by muse, mutect2
- GNPTG | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1331412160, COSV99136126; called by muse, varscan2
- GPN2 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100658692; called by muse, mutect2, varscan2
- GRAMD4 | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV100730297; called by muse, mutect2, varscan2
- HCK | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV99393722; called by muse, mutect2
- HDAC6 | c.2701G>T p.A901S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV100490553; called by muse, mutect2
- HIVEP1 | c.6341G>T p.R2114L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV101044689; called by muse, mutect2
- HSPA12B | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99653828; called by mutect2, varscan2
- IRF8 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs778129733, COSV51896629, COSV51899822; called by muse, mutect2, varscan2
- KIF21B | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100143590; called by muse, mutect2
- KLF7 | c.348C>A p.S116R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100518971; called by mutect2, varscan2
- LAIR1 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100479427; called by muse, mutect2, varscan2
- LCE1B | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100780253; called by muse, mutect2, varscan2
- LIMCH1 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1426637075, COSV100573371; called by muse, mutect2
- LRRC59 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99869353; called by muse, mutect2
- MED25 | c.1353G>T p.Q451H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV57207844; called by muse, mutect2, varscan2
- MICAL3 | c.1591C>A p.Q531K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV99259854; called by muse, mutect2
- MIDEAS | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.219); catalogued as COSV99678561; called by muse, varscan2
- MME | c.1780+2T>C p.X594_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100852240, COSV64708303; called by muse, mutect2, varscan2
- MMP9 | c.2109G>C p.Q703H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100812344; called by muse, mutect2, varscan2
- MOV10L1 | c.3216+2T>C p.X1072_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99432646; called by muse, mutect2, varscan2
- MRPS23 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100551406; called by muse, mutect2, varscan2
- MYBPC2 | c.2579T>C p.L860P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100731570; called by mutect2, varscan2
- MYO1E | c.2050C>A p.L684I | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV99894330; called by muse, mutect2
- MYO3B | c.3290-1G>T p.X1097_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100509147; called by mutect2, varscan2
- MYT1 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as COSV100113945; called by muse, mutect2, varscan2
- MYT1L | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746083137, COSV67714781; called by muse, mutect2, varscan2
- NBEAL2 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV99434407; called by muse, mutect2, varscan2
- NECTIN2 | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52976057; called by muse, mutect2
- NELFE | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100952585; called by muse, mutect2, varscan2
- NMRK2 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 14/274 reads (5%) | catalogued as COSV99396236; called by muse, mutect2
- NRM | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.212); catalogued as COSV99223548; called by mutect2, varscan2
- NUGGC | c.2005C>A p.L669I | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100428882; called by muse, mutect2
- OGFR | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV99283690; called by muse, varscan2
- OR9Q2 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100285310; called by muse, mutect2, varscan2
- PAM | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV99173040; called by muse, mutect2, varscan2
- PCDHA11 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs782319322, COSV100247570; called by muse, mutect2, varscan2
- PCDHB10 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV99503644; called by muse, mutect2, varscan2
- PCGF1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.956); catalogued as COSV99283172; called by muse, mutect2, varscan2
- PCLO | c.3510A>T p.K1170N | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV61615769; called by muse, mutect2
- PLXNB1 | c.2374C>A p.L792M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as COSV99602228; called by muse, mutect2, varscan2
- PMS2 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as rs756127972, COSV56222696; called by muse, mutect2, varscan2
- POM121 | c.3218T>G p.F1073C (on ENST00000434423; = p.F808C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99987565; called by muse, mutect2, varscan2
- POU6F2 | c.1076C>G p.A359G | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV101302443; called by muse, mutect2
- PPP4R1 | c.584C>A p.A195D (on ENST00000400556 / NM_001042388.3; = p.A178D on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99553137; called by mutect2, varscan2
- PRIM2 | c.318G>T p.L106F | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99227914; called by muse, mutect2
- PSD4 | c.2292G>T p.K764N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99830818; called by mutect2, varscan2
- PTPN23 | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.163); catalogued as COSV55542357; called by muse, varscan2
- PTPRO | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.727); catalogued as rs371348326; called by muse, mutect2, varscan2
- PYROXD1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99556267; called by muse, mutect2
- RAF1 | c.1859C>A p.A620D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV50103949; called by mutect2, varscan2
- RBMS2 | c.1161G>T p.Q387H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100008355; called by muse, mutect2
- RBMS3 | c.1129A>T p.T377S (on ENST00000383767 / NM_001003793.3; = p.T361S on NM_014483.3) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV99819285; called by muse, mutect2, varscan2
- RCOR3 | c.633G>T p.Q211H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.401); catalogued as COSV100879468; called by muse, mutect2, varscan2
- RIC8B | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822436; called by muse, mutect2
- RNF216 | c.1688G>A p.S563N (on ENST00000425013 / NM_207116.3; = p.S620N on NM_207111.4) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV101111260; called by muse, mutect2, varscan2
- SCNN1B | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs777888930, COSV56303070; called by muse, mutect2, varscan2
- SLFN13 | c.2159C>A p.A720E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1292824983, COSV99539714; called by muse, mutect2
- SLIT1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754904853, COSV56595622; called by muse, mutect2, varscan2
- SPECC1L | c.1874G>T p.S625I | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV100061689; called by muse, mutect2
- SPEM2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs761895904, COSV61603194; called by muse, mutect2, varscan2
- ST6GAL1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 15/25 reads (60%) | PolyPhen probably damaging (0.987); catalogued as rs527877833, COSV51476162; called by muse, mutect2, varscan2
- SUPT5H | c.2051T>G p.F684C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV100781905; called by muse, mutect2, varscan2
- TLE3 | c.486C>A p.S162R | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV100450042; called by muse, mutect2
- TMEM130 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.146); catalogued as COSV100228532; called by muse, mutect2, varscan2
- TMEM184B | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV100725901; called by muse, mutect2, varscan2
- TRABD | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV57713937; called by muse, mutect2
- TSC22D2 | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100721182; called by muse, mutect2, varscan2
- UBE2W | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100708645; called by muse, mutect2, varscan2
- USH2A | c.4637C>A p.A1546D | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs1261171382, COSV100228902; called by muse, mutect2
- USP54 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100160914; called by mutect2, varscan2
- XPC | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749104732, COSV53207083, COSV99542063; called by mutect2, varscan2
- ZBTB34 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100043548; called by muse, mutect2, varscan2
- ZFYVE1 | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as COSV100606511; called by muse, mutect2, varscan2
- ZMYND8 | c.884C>A p.A295D (on ENST00000311275 / NM_001363741.2; = p.A315D on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99519526; called by muse, mutect2
- ZNF197 | c.1478A>T p.Q493L | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.795); catalogued as COSV100481989; called by muse, mutect2, varscan2
- ADRA1A | c.645C>A p.S215R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2
- AGBL5 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CREBRF | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FRMPD2 | c.1526C>A p.A509D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by mutect2, varscan2
- GPX5 | c.8del p.T3Nfs*3 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- GRM8 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GTPBP1 | c.2000G>T p.S667I | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- LRRC27 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDE1C | c.1523C>A p.A508D | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.051); called by muse, mutect2
- PGBD1 | c.396+1G>T p.X132_splice | Splice Site (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- PYHIN1 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.293); called by muse, mutect2
- RNF166 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.046); called by muse, varscan2
- ABCC2 | c.4068T>A p.G1356= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100966388; called by muse, mutect2, varscan2
- AC068580.4 | c.867C>A p.G289= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99362223; called by mutect2, varscan2
- AMPH | c.240G>A p.S80= | Silent (SNP) | VAF 18/231 reads (8%) | catalogued as rs773721004, COSV100343695, COSV57744871; called by muse, mutect2
- ASAP1 | c.2103C>A p.V701= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV100726819; called by muse, varscan2
- DMRT1 | c.885G>A p.P295= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs771988103, COSV101206605; called by muse, varscan2
- DNAH1 | c.8112G>T p.G2704= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101324674; called by mutect2, varscan2
- DYRK4 | c.1119C>T p.F373= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs866797875, COSV99155345; called by muse, mutect2, varscan2
- FFAR2 | c.255G>A p.T85= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1364784849, COSV55833009; called by muse, mutect2, varscan2
- FLT4 | c.2799C>A p.G933= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- HHIPL2 | c.1338C>A p.G446= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100596585; called by mutect2, varscan2
- KCNQ3 | c.1191G>A p.A397= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs763718116, COSV66467604; called by muse, mutect2, varscan2
- LLGL2 | c.2433G>T p.L811= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- MAP3K9 | c.1008G>A p.G336= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV101173457; called by muse, mutect2, varscan2
- MARK2 | c.543G>T p.L181= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100158053; called by muse, mutect2
- MYH6 | c.4746C>T p.D1582= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781492953, COSV62451934; called by muse, mutect2, varscan2
- NBEAL2 | c.3225G>T p.P1075= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV99434412; called by muse, mutect2, varscan2
- OR2AT4 | c.837C>A p.G279= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100532260, COSV100532357; called by muse, mutect2
- PRKCA | c.597A>G p.K199= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99433610; called by muse, mutect2, varscan2
- TTBK1 | c.2526C>T p.G842= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs754151759, COSV99443646; called by muse, mutect2, varscan2
- ZNF624 | c.2526A>G p.G842= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100256998; called by muse, mutect2, varscan2
- CIT | c.2082+1868C>A | Intron (SNP) | VAF 7/84 reads (8%) | catalogued as COSV99948354; called by muse, mutect2
- SLC48A1 | c.*221G>T | 3'UTR (SNP) | VAF 7/98 reads (7%) | catalogued as COSV99315550; called by muse, mutect2
